Somatic mutation profile of tumor specimen TCGA-29-2427-01A (aliquot TCGA-29-2427-01A-01W-0799-08) from TCGA case TCGA-29-2427, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.1 years (21,940 days).
Specimen TCGA-29-2427-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35b3447e-6952-4300-8789-b10b844e421f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-2427-10A (Blood Derived Normal), aliquot TCGA-29-2427-10A-01W-0800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0dd3fb9a-f05f-4547-8498-4c1e9603de9d

The open-access MAF lists 75 somatic variants for this specimen: 54 protein-altering or splice-affecting, 21 silent.
By variant classification: Missense Mutation 41, Silent 21, Frame Shift Del 4, Nonsense Mutation 3, Splice Site 3, Frame Shift Ins 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.1292T>G p.L431* | Nonsense Mutation (SNP) | VAF 65/116 reads (56%) | catalogued as rs80357346, CD1210116, CM984068, COSV58787117; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.2483G>A p.G828E | Missense Mutation (SNP) | VAF 58/219 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs281874695, CM113175, COSV100088106; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 145/306 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AHCTF1 | c.358G>A p.E120K (on ENST00000366508; = p.E94K on NM_015446.5) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV58247935; called by muse, mutect2, varscan2
- AIFM1 | c.1779G>C p.K593N | Missense Mutation (SNP) | VAF 112/387 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.075); catalogued as COSV54853625; called by muse, mutect2, varscan2
- BUB1 | c.1601A>G p.N534S | Missense Mutation (SNP) | VAF 80/211 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV57062240; called by muse, mutect2, varscan2
- CACNG6 | c.342C>A p.C114* | Nonsense Mutation (SNP) | VAF 31/60 reads (52%) | catalogued as COSV53166195; called by muse, mutect2, varscan2
- CHPF2 | c.835C>A p.Q279K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.183); catalogued as COSV50389516; called by muse, mutect2, varscan2
- CLASP1 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV55319326; called by muse, mutect2, varscan2
- CSMD3 | c.6366C>G p.I2122M (on ENST00000297405 / NM_001363185.1; = p.I2018M on NM_052900.3) | Missense Mutation (SNP) | VAF 63/385 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52140814; called by muse, mutect2, varscan2
- CYP26B1 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50011353; called by muse, mutect2, varscan2
- DNAH8 | c.8528A>C p.Q2843P | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59435110; called by muse, mutect2, varscan2
- EPHA10 | c.3025T>C p.*1009Rext*67 | Nonstop Mutation (SNP) | VAF 30/66 reads (45%) | catalogued as COSV100361483; called by muse, mutect2
- EWSR1 | c.1240A>G p.T414A | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as COSV58422597; called by muse, mutect2, varscan2
- FGD3 | c.1640C>G p.S547C | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100490840, COSV61596513; called by muse, varscan2
- FIGN | c.1321C>A p.P441T | Missense Mutation (SNP) | VAF 176/550 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV60764860; called by muse, mutect2, varscan2
- GABRA6 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 92/267 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1294504139, COSV50879096; called by muse, mutect2, varscan2
- GCNA | c.1213C>G p.P405A | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV65466293; called by muse, mutect2, varscan2
- GFI1 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs776862077, COSV54042222; called by muse, mutect2, varscan2
- HHATL | c.1039C>A p.L347I | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV55133617; called by muse, mutect2, varscan2
- HLA-G | c.899A>C p.Q300P | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs766671384, COSV64405397; called by muse, mutect2, varscan2
- HSD17B4 | c.1270A>G p.I424V (on ENST00000414835 / NM_001199291.3; = p.I399V on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 123/345 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV56334555; called by muse, mutect2, varscan2
- JPH4 | c.1271-2A>T p.X424_splice | Splice Site (SNP) | VAF 31/78 reads (40%) | catalogued as COSV58111332; called by muse, mutect2, varscan2
- KIAA1109 | c.2176G>C p.E726Q | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52667149; called by muse, mutect2, varscan2
- KIF14 | c.4654C>T p.P1552S | Missense Mutation (SNP) | VAF 109/300 reads (36%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV66260929; called by muse, mutect2, varscan2
- LPA | c.4841G>A p.R1614Q | Missense Mutation (SNP) | VAF 271/504 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777960988, COSV60299685; called by muse, mutect2, varscan2
- MIGA1 | c.95C>A p.A32D | Missense Mutation (SNP) | VAF 145/418 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV66222849, COSV66223258; called by muse, mutect2, varscan2
- MPP4 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs377589827; called by muse, mutect2, varscan2
- NSUN2 | c.1134C>G p.D378E | Missense Mutation (SNP) | VAF 82/265 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as COSV99243285; called by muse, mutect2, varscan2
- NTNG2 | c.313A>C p.T105P | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62365806; called by muse, varscan2
- NUP155 | c.2038G>C p.A680P (on ENST00000231498 / NM_153485.3; = p.A621P on NM_004298.4) | Missense Mutation (SNP) | VAF 48/207 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.127); catalogued as COSV99193440; called by muse, mutect2, varscan2
- ODAM | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 87/348 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as COSV68572548, COSV68573508; called by muse, mutect2, varscan2
- PAAF1 | c.461T>A p.M154K | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV60154966; called by muse, mutect2, varscan2
- PLAC8 | c.119-1G>T p.X40_splice | Splice Site (SNP) | VAF 21/48 reads (44%) | catalogued as COSV61047129; called by muse, mutect2, varscan2
- PRMT8 | c.750C>G p.I250M | Missense Mutation (SNP) | VAF 469/882 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV54212936; called by muse, mutect2, varscan2
- PTPRN2 | c.1672G>A p.V558M | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1197495157, COSV67030512, COSV67034545; called by muse, mutect2, varscan2
- RAB10 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53088953; called by muse, mutect2, varscan2
- RNF145 | c.1067C>G p.S356C (on ENST00000424310 / NM_001199383.2; = p.S384C on NM_144726.2) | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99193640; called by muse, mutect2
- SEPTIN6 | c.1112T>G p.L371R | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100595668; called by muse, mutect2
- SYNE1 | c.18614C>A p.T6205K (on ENST00000367255 / NM_182961.4; = p.T6134K on NM_033071.3) | Missense Mutation (SNP) | VAF 123/241 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.051); catalogued as COSV54943544; called by muse, mutect2, varscan2
- TRPV1 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs768953121, COSV51517033; called by muse, mutect2, varscan2
- TTN | c.93202A>T p.R31068* (on ENST00000591111; = p.R23644* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 86/234 reads (37%) | catalogued as COSV59964202; called by muse, mutect2, varscan2
- ZNF225 | c.1893G>C p.K631N | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99489507; called by muse, mutect2
- ZNF621 | c.620A>G p.Y207C | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1327309818, COSV59457657; called by muse, mutect2, varscan2
- ZNF70 | c.850C>G p.L284V | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV59532513, COSV59533555; called by muse, mutect2, varscan2
- ZNFX1 | c.4358T>G p.F1453C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV65595707; called by muse, mutect2, varscan2
- GANC | c.1091del p.G364Dfs*15 | Frame Shift Del (DEL) | VAF 56/234 reads (24%) | called by mutect2, pindel, varscan2
- IGKV2-24 | c.61G>C p.D21H | Missense Mutation (SNP) | VAF 137/403 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- KIF4A | c.3261dup p.C1088Lfs*26 | Frame Shift Ins (INS) | VAF 66/252 reads (26%) | called by mutect2, pindel, varscan2
- KMT2C | c.13163_13212del p.T4388Mfs*3 | Frame Shift Del (DEL) | VAF 39/177 reads (22%) | called by mutect2, pindel
- MS4A8 | c.73del p.V25* | Frame Shift Del (DEL) | VAF 555/1934 reads (29%) | called by mutect2, pindel, varscan2
- PRMT9 | c.2200-7_2205del p.X734_splice | Splice Site (DEL) | VAF 40/267 reads (15%) | called by mutect2, pindel, varscan2
- VPS13A | c.2981del p.L994Wfs*11 | Frame Shift Del (DEL) | VAF 52/175 reads (30%) | called by mutect2, pindel, varscan2
- ZNF573 | c.510dup p.F171Lfs*3 (on ENST00000536220 / NM_001172692.1; = p.F113Lfs*3 on NM_152360.3) | Frame Shift Ins (INS) | VAF 134/410 reads (33%) | called by mutect2, pindel, varscan2
- ARHGAP31 | c.4129A>C p.R1377= | Silent (SNP) | VAF 47/1256 reads (4%) | catalogued as COSV99957279; called by muse, mutect2
- C5 | c.3756C>G p.A1252= | Silent (SNP) | VAF 156/456 reads (34%) | catalogued as COSV56325715; called by muse, mutect2, varscan2
- CARD11 | c.1719C>T p.I573= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs762267654, COSV62754698; called by muse, mutect2, varscan2
- CD33 | c.750A>G p.K250= | Silent (SNP) | VAF 77/143 reads (54%) | catalogued as COSV99220535; called by muse, mutect2, varscan2
- COL4A5 | c.2484G>T p.G828= | Silent (SNP) | VAF 55/214 reads (26%) | catalogued as COSV100088113, COSV60360337; called by muse, mutect2, varscan2
- CROCC | c.2109G>A p.K703= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- GPR63 | c.351C>T p.N117= | Silent (SNP) | VAF 78/272 reads (29%) | catalogued as COSV57740532; called by muse, mutect2, varscan2
- GRIA1 | c.2694G>A p.G898= | Silent (SNP) | VAF 65/171 reads (38%) | catalogued as COSV53596558; called by muse, mutect2, varscan2
- IGKV2-30 | c.90C>T p.S30= | Silent (SNP) | VAF 94/369 reads (25%) | called by muse, mutect2, varscan2
- IST1 | c.465A>G p.G155= (on ENST00000535424 / NM_001270976.1; = p.G142= on NM_014761.4) | Silent (SNP) | VAF 12/164 reads (7%) | catalogued as COSV61709177; called by muse, mutect2
- LLGL1 | c.1230C>A p.A410= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV57497016; called by muse, mutect2, varscan2
- MGAT4C | c.219C>T p.F73= | Silent (SNP) | VAF 74/146 reads (51%) | catalogued as COSV59831442, COSV59836087; called by muse, mutect2, varscan2
- MROH2B | c.2349T>A p.I783= | Silent (SNP) | VAF 94/327 reads (29%) | catalogued as COSV68182598; called by muse, mutect2, varscan2
- NCAPG2 | c.867C>T p.F289= | Silent (SNP) | VAF 78/296 reads (26%) | catalogued as COSV51986194; called by muse, mutect2, varscan2
- PTGIR | c.438C>T p.F146= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV52191722, COSV52193802; called by muse, mutect2
- SPATA5L1 | c.2106G>T p.L702= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV59744285; called by muse, mutect2, varscan2
- SZT2 | c.5682G>A p.R1894= (on ENST00000634258 / NM_001365999.1; = p.R1837= on NM_015284.4) | Silent (SNP) | VAF 99/249 reads (40%) | catalogued as COSV65168485; called by muse, mutect2, varscan2
- TMEM53 | c.756C>T p.H252= | Silent (SNP) | VAF 80/218 reads (37%) | catalogued as rs1039882941, COSV59190180; called by muse, mutect2, varscan2
- TRIM36 | c.1503A>G p.R501= | Silent (SNP) | VAF 105/287 reads (37%) | catalogued as COSV56689415; called by muse, mutect2, varscan2
- UBOX5 | c.651G>A p.L217= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV53905135; called by muse, mutect2, varscan2
- ZFYVE26 | c.3114T>G p.L1038= | Silent (SNP) | VAF 40/83 reads (48%) | catalogued as COSV61325036; called by muse, mutect2, varscan2
